Somatic mutation profile of tumor specimen MMRF_1972_2_BM_CD138pos (aliquot MMRF_1972_2_BM_CD138pos_T1_KHS5U_L16533) from MMRF case MMRF_1972, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.1 years (29,977 days).
Specimen MMRF_1972_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5812deec-a83a-4f68-8103-00ce232f9f11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1972_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1972_1_PB_Whole_C3_KBS5U_L07265; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fdf2486-6e2c-42e6-b54f-fc412b1bd54b

The open-access MAF lists 205 somatic variants for this specimen: 87 protein-altering or splice-affecting, 30 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, 3'UTR 40, Silent 30, Intron 30, Nonsense Mutation 8, 5'UTR 8, 5'Flank 5, RNA 3, Splice Site 3, Frame Shift Del 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/234 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANLN | c.3362T>C p.I1121T | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1218381226; called by muse, mutect2, varscan2
- ATM | c.3077+2T>C p.X1026_splice | Splice Site (SNP) | VAF 10/186 reads (5%) | catalogued as COSV53781228; called by muse, mutect2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- CARD10 | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99324850; called by muse, mutect2, varscan2
- COL4A1 | c.2377G>C p.V793L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.185); catalogued as rs769302846; called by muse, mutect2, varscan2
- DLL1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 11/222 reads (5%) | catalogued as COSV64538959; called by muse, mutect2
- EHD1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 98/156 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs761533385, COSV100277209; called by muse, mutect2, varscan2
- F2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs200934494; called by muse, mutect2, varscan2
- FLNC | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs775085661, COSV57958345, COSV57966882; called by muse, mutect2, varscan2
- FRS3 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs762000716; called by muse, mutect2, varscan2
- IGHD2-2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as rs535073705; called by muse, mutect2, varscan2
- IGHV2-70 | c.228T>G p.D76E | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs373802343; called by muse, varscan2
- MAB21L3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs761323415, COSV65673750; called by muse, mutect2, varscan2
- MICAL3 | c.3493G>T p.A1165S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs779450964; called by mutect2, varscan2
- NOD2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.222); catalogued as rs760938311, COSV56053693; called by muse, mutect2, varscan2
- NT5E | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1376026847; called by muse, mutect2, varscan2
- PCSK5 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as rs200049619, COSV65085478; called by muse, mutect2, varscan2
- PDZRN3 | c.1478A>T p.N493I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.552); catalogued as COSV55202526; called by muse, mutect2, varscan2
- POLR3B | c.10del p.L4* | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | catalogued as COSV57278737; called by mutect2, pindel, varscan2
- PRLHR | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53305010; called by muse, mutect2, varscan2
- PSMB9 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841365; called by muse, mutect2
- PTCHD1 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 75/80 reads (94%) | SIFT tolerated (0.58); PolyPhen benign (0.104); catalogued as rs753840664; called by muse, mutect2, varscan2
- RASD2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs770684908, COSV53353440, COSV99332763; called by muse, mutect2, varscan2
- SPAG17 | c.4529G>A p.C1510Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770774268; called by muse, mutect2, varscan2
- TLL1 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); catalogued as COSV50310750; called by muse, mutect2, varscan2
- TOX3 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54869325; called by muse, mutect2, varscan2
- TSPOAP1 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs766215697, COSV99272490; called by muse, mutect2, varscan2
- ZIC4 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101268196; called by muse, mutect2, varscan2
- ZNF132 | c.1759A>G p.I587V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs1028134336; called by muse, mutect2
- ZNF541 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs751201378; called by muse, mutect2, varscan2
- ADGRG6 | c.3056T>C p.V1019A | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ARGLU1 | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- AUTS2 | c.188del p.P63Rfs*31 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- AZGP1 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRWD1 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2
- BTBD10 | c.877A>C p.I293L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C9orf64 | c.338-9_351del p.X113_splice | Splice Site (DEL) | VAF 78/359 reads (22%) | called by mutect2, pindel, varscan2
- CADM2 | c.1063+1G>A p.X355_splice (on ENST00000407528 / NM_001167674.2; = p.X357_splice on NM_153184.4) | Splice Site (SNP) | VAF 11/381 reads (3%) | called by muse, mutect2
- CAMSAP1 | c.4088C>G p.S1363* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- CCNC | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 52/156 reads (33%) | called by muse, varscan2
- CFAP74 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CMPK2 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- COL5A3 | c.4378G>A p.G1460R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DACH2 | c.1717A>C p.N573H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DRAP1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ENC1 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPB41 | c.2026G>T p.E676* (on ENST00000343067 / NM_001166005.2; = p.E434* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | called by mutect2, varscan2
- EVC | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.116); called by muse, mutect2
- FAT2 | c.7913C>T p.P2638L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FBXL2 | c.951+8T>C | Splice Region (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- GRIA3 | c.1802A>C p.N601T | Missense Mutation (SNP) | VAF 146/155 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRF6 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KATNAL2 | c.860G>A p.W287* (on ENST00000356157 / NM_001353899.1; = p.W215* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- KIF4B | c.3078dup p.P1027Tfs*5 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- KMT2B | c.4739A>G p.Q1580R | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LGALS9 | c.1022G>C p.R341T (on ENST00000395473 / NM_009587.3; = p.R309T on NM_002308.4) | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP2 | c.12199T>A p.Y4067N | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MATN2 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUPR2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR10G8 | c.930C>A p.S310R | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4D11 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PARP6 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PTPRK | c.3721C>T p.P1241S (on ENST00000368215 / NM_001291984.2; = p.P1242S on NM_002844.4) | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RASEF | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO3 | c.3286T>A p.C1096S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.201); called by muse, varscan2
- RP1 | c.3235C>A p.Q1079K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- SARDH | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SCPEP1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SEC16A | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2
- SLCO1B3 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, varscan2
- SYT4 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC1 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TMEM200C | c.666_674dup p.A228_A230dup | In Frame Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- TNFSF15 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TOPBP1 | c.1876_1879del p.F626Ifs*13 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by pindel, varscan2
- TOX3 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSEN15 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UGGT2 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- UNK | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- VCPKMT | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.4931T>C p.V1644A (on ENST00000628543; = p.V1819A on NM_152381.6) | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ZNF274 | c.1250T>C p.V417A (on ENST00000610905; = p.V312A on NM_016324.3) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF574 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ZNF618 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- ZNF792 | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRA1 | c.525C>T p.S175= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1281786187; called by muse, mutect2, varscan2
- AL031777.2 | c.141C>A p.G47= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs370218182; called by muse, mutect2, varscan2
- B3GNT7 | c.751C>T p.L251= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as rs1384019828; called by muse, mutect2, varscan2
- BCHE | c.987C>T p.D329= | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as rs766000843; called by muse, mutect2, varscan2
- CHST12 | c.888C>G p.L296= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- CLCN7 | c.2346G>C p.V782= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs1200061529; called by muse, mutect2
- DUSP2 | c.343C>T p.L115= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs542663886; called by muse, mutect2, varscan2
- DYDC2 | c.174G>A p.Q58= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- EPRS1 | c.318G>A p.L106= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- EXOSC6 | c.573C>T p.P191= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- FLRT2 | c.1971C>T p.H657= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- GJA8 | c.1164G>A p.S388= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as rs377042749, COSV99569424; called by muse, mutect2, varscan2
- IGLL5 | c.78G>C p.L26= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV73250938; called by muse, varscan2
- KCNN2 | c.39G>C p.P13= (on ENST00000264773; = p.P225= on NM_021614.4) | Silent (SNP) | VAF 79/252 reads (31%) | catalogued as COSV53295087; called by muse, mutect2, varscan2
- KCNS1 | c.585C>T p.G195= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- MAGEA10 | c.684A>T p.I228= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- OR4M1 | c.51A>G p.L17= | Silent (SNP) | VAF 14/407 reads (3%) | catalogued as COSV60062313; called by muse, mutect2
- PRICKLE1 | c.88T>C p.L30= | Silent (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1995T>C p.V665= | Silent (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- RANBP2 | c.8385A>G p.E2795= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs774055387; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHCG | c.972G>A p.L324= | Silent (SNP) | VAF 87/295 reads (29%) | called by muse, mutect2, varscan2
- RIF1 | c.1566A>G p.P522= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- RNASEH2C | c.129G>A p.P43= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs774676282, COSV100383832; called by muse, mutect2, varscan2
- SHANK1 | c.3807C>T p.D1269= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1545C>T p.P515= | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as rs1396577157, COSV99214408; called by muse, mutect2
- TAPT1 | c.9C>T p.G3= | Silent (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- TP63 | c.951C>T p.N317= | Silent (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- TRIM71 | c.1947G>T p.R649= | Silent (SNP) | VAF 120/196 reads (61%) | called by muse, mutect2, varscan2
- TRPM5 | c.1233G>A p.T411= | Silent (SNP) | VAF 56/277 reads (20%) | catalogued as rs199917878; called by muse, mutect2, varscan2
- ZNF718 | c.1314G>A p.L438= | Silent (SNP) | VAF 5/39 reads (13%) | called by mutect2, varscan2
- AC078899.4 | n.588G>T | RNA (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- AMOTL2 | c.*488C>T | 3'UTR (SNP) | VAF 72/241 reads (30%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*315G>A | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- BBS4 | c.*97C>T | 3'UTR (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- BMP5 | c.*441A>T | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- BST2 | c.-7G>A | 5'UTR (SNP) | VAF 12/284 reads (4%) | catalogued as rs1365074910; called by muse, mutect2
- C1QL3 | chr10:16521983 G>A | 5'Flank (SNP) | VAF 7/30 reads (23%) | catalogued as rs748671695; called by muse, mutect2, varscan2
- CAPRIN1 | c.*1405A>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- CCDC110 | c.2461+828C>G | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- CCDC186 | c.*2547T>C | 3'UTR (SNP) | VAF 57/117 reads (49%) | catalogued as rs1027206016; called by muse, mutect2, varscan2
- CCNC | c.346+51C>G | Intron (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- CELF5 | c.*40+14C>A | Intron (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2
- CEP170 | c.*1743C>T | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- COA1 | c.-38-1184G>A | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2190-27C>T | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as rs13408126; called by muse, mutect2, varscan2
- CXCL1 | c.*161_*164del | 3'UTR (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- DDX53 | c.-68G>A | 5'UTR (SNP) | VAF 34/38 reads (89%) | called by muse, mutect2, varscan2
- DLL1 | c.*159C>T | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs574425432; called by muse, mutect2, varscan2
- FAM229B | c.*1714A>G | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- FGF23 | c.*598C>T | 3'UTR (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- FLRT3 | c.*479A>T | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- FNIP1 | c.*2970G>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035367 G>A | 5'Flank (SNP) | VAF 59/180 reads (33%) | catalogued as rs1178630193; called by muse, mutect2, varscan2
- GABRB3 | c.*3784C>T | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- GABRG1 | c.*4300C>T | 3'UTR (SNP) | VAF 21/103 reads (20%) | catalogued as rs956113674; called by muse, mutect2, varscan2
- GADL1 | c.1250+2410C>G | Intron (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- GET4 | c.156-1255G>T | Intron (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- GPSM1 | c.*851A>G | 3'UTR (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- GREM1 | c.-19G>T | 5'UTR (SNP) | VAF 18/100 reads (18%) | catalogued as rs1295322956; called by muse, mutect2, varscan2
- H4C9 | c.*146C>T | 3'UTR (SNP) | VAF 35/69 reads (51%) | catalogued as rs1458825172, COSV104416474; called by muse, mutect2, varscan2
- HACD2 | c.682+1190A>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- HDX | c.*2214A>G | 3'UTR (SNP) | VAF 21/29 reads (72%) | called by muse, mutect2, varscan2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- KBTBD12 | c.*2627C>T | 3'UTR (SNP) | VAF 14/132 reads (11%) | catalogued as rs978088669; called by muse, mutect2
- KDM4A | c.*1057C>A | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53511821; called by muse, mutect2, varscan2
- LHX8 | c.-382G>A | 5'UTR (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
- LILRA5 | c.*151T>C | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs911924738; called by mutect2, varscan2
- LOX | c.*884del | 3'UTR (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- MACROD2 | chr20:16051244 A>T | 3'Flank (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- MAGI1 | c.2168-199C>T | Intron (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- MCC | c.*2266C>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- MCL1 | c.688+12C>T | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- MCM10 | chr10:13211047 G>A | 3'Flank (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- MIR513C | n.78T>C | RNA (SNP) | VAF 136/142 reads (96%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46112210 A>C | 5'Flank (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- MTNR1B | c.223+2583A>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- MYO1F | c.141+131G>A | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as rs1404397741; called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604455 G>T | 5'Flank (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- NECAB1 | c.*2834T>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- NFATC4 | chr14:24367391 C>G | 5'Flank (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- NOL8 | c.*93_*94del | 3'UTR (DEL) | VAF 48/159 reads (30%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1397-55030G>A | Intron (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- NUCKS1 | c.*2253G>A | 3'UTR (SNP) | VAF 17/39 reads (44%) | catalogued as rs1446730545; called by muse, mutect2, varscan2
- NUP58 | c.*1542G>T | 3'UTR (SNP) | VAF 59/203 reads (29%) | called by muse, mutect2, varscan2
- PADI2 | c.*479T>A | 3'UTR (SNP) | VAF 47/104 reads (45%) | catalogued as rs1325729765; called by muse, mutect2, varscan2
- PCDHA10 | c.2388+3849G>T | Intron (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- PDIA3P1 | n.1896A>G | RNA (SNP) | VAF 57/152 reads (38%) | called by muse, mutect2, varscan2
- PDK2 | c.260+37C>A | Intron (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2
- PDPK1 | c.*3335G>A | 3'UTR (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- PLK2 | c.-114G>A | 5'UTR (SNP) | VAF 11/133 reads (8%) | catalogued as rs918723338; called by muse, mutect2
- PRKCB | c.1864-169C>T | Intron (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.*4909C>T | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- RBBP8NL | c.-50G>A | 5'UTR (SNP) | VAF 28/95 reads (29%) | catalogued as rs753572760; called by muse, mutect2, varscan2
- RGL1 | c.*634C>T | 3'UTR (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- RPS27L | c.7-135T>C | Intron (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- SDC1 | c.*716_*735del | 3'UTR (DEL) | VAF 12/57 reads (21%) | called by mutect2, varscan2
- SDCBP2 | c.225+11G>A | Intron (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- SERPINA3 | c.-8-901A>G | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- SESN3 | c.-156C>G | 5'UTR (SNP) | VAF 23/32 reads (72%) | catalogued as rs1430862061; called by muse, varscan2
- SHMT2 | c.*573C>T | 3'UTR (SNP) | VAF 5/92 reads (5%) | catalogued as rs958232321; called by muse, mutect2
- SLC24A5 | c.301+976T>A | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SLC28A1 | c.461+635_461+636insA | Intron (INS) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- SLC37A3 | c.*1440C>T | 3'UTR (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.147+49C>A | Intron (SNP) | VAF 10/33 reads (30%) | called by mutect2, varscan2
- SPEG | c.389-3111G>T | Intron (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- STK4 | c.*54G>A | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-1269G>A | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- TMEM196 | c.*936C>T | 3'UTR (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- TMPRSS5 | c.*15T>C | 3'UTR (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- TNFSF15 | c.302-319G>A | Intron (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- TNFSF15 | c.301+658G>C | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2
- TRIM36 | c.63+2652T>A | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- TRIO | c.*1273G>A | 3'UTR (SNP) | VAF 22/103 reads (21%) | catalogued as rs1402533897; called by muse, mutect2, varscan2
- TRPV3 | c.*992C>T | 3'UTR (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2
- UXS1 | c.969+75G>T | Intron (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- WDR55 | c.*2599G>T | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+905T>C | Intron (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- ZNF846 | c.15+25C>G | Intron (SNP) | VAF 46/251 reads (18%) | called by muse, mutect2, varscan2
